Somatic mutation profile of tumor specimen MP2PRT-PATTSM-TMP1-A (aliquot MP2PRT-PATTSM-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATTSM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (846 days).
Specimen MP2PRT-PATTSM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6666394-1279-422d-9721-24591dbf9436.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATTSM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATTSM-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eab00012-6105-4404-b838-610f84292e9a

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRM3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 56/717 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV64471156; called by muse, mutect2
- MAP7 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs758752026; called by muse, mutect2, varscan2
- PRSS12 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 176/444 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs778632400, COSV56607334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF112 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 71/590 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs756085950, COSV71978977; called by muse, mutect2, varscan2
- UGGT1 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52132766; called by muse, varscan2
- VRTN | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 77/600 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1330449009, COSV56440995, COSV56441603; called by muse, mutect2, varscan2
- ZNF521 | c.724A>G p.M242V | Missense Mutation (SNP) | VAF 24/505 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs1021240858; called by muse, mutect2
- XG | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARMC5 | c.48C>T p.L16= | Silent (SNP) | VAF 27/912 reads (3%) | catalogued as COSV51655029, COSV51657963, COSV51659455; called by muse, mutect2
- CYBA | c.567G>A p.P189= | Silent (SNP) | VAF 20/563 reads (4%) | catalogued as rs1407529453; ClinVar: uncertain significance; called by muse, mutect2
- DDX19A | c.681C>T p.L227= | Silent (SNP) | VAF 70/546 reads (13%) | catalogued as COSV56358836; called by muse, mutect2, varscan2
- KCNH8 | c.273A>T p.T91= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as COSV60472435; called by muse, mutect2, varscan2
- TNC | c.627C>T p.D209= | Silent (SNP) | VAF 85/537 reads (16%) | catalogued as rs138151398; called by muse, mutect2, varscan2
